Somatic mutation profile of tumor specimen TCGA-13-0807-01B (aliquot TCGA-13-0807-01B-02W-0420-08) from TCGA case TCGA-13-0807, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 54.5 years (19,890 days).
Specimen TCGA-13-0807-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8077fc6e-6a30-4b8a-ad99-5f12f0610e22.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0807-10A (Blood Derived Normal), aliquot TCGA-13-0807-10A-01W-0420-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d399bc6-a451-444a-bede-4889f0a0d240

The open-access MAF lists 202 somatic variants for this specimen: 143 protein-altering or splice-affecting, 54 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 124, Silent 54, Nonsense Mutation 12, Splice Site 3, Intron 2, 5'Flank 2, In Frame Del 1, RNA 1, In Frame Ins 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PHEX | c.933+1G>T p.X311_splice | Splice Site (SNP) | VAF 59/191 reads (31%) | catalogued as rs1556025314, CS971857, COSV65073787, COSV65078280; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.826G>C p.A276P | Missense Mutation (SNP) | VAF 128/216 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.569); catalogued as rs1131691029, COSV52731052, COSV52823875, COSV52978993; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACD | c.597C>T p.P199= (on ENST00000620338; = p.P110= on NM_022914.3) | Splice Region (SNP) | VAF 24/73 reads (33%) | catalogued as rs1322815478, COSV54667662; called by muse, mutect2, varscan2
- ACSS1 | c.1816G>A p.D606N | Missense Mutation (SNP) | VAF 98/573 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100053951; called by muse, mutect2, varscan2
- ADAM7 | c.1820G>A p.G607E | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99443010, COSV99444672; called by muse, varscan2
- ADAMTS8 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV99961373; called by muse, varscan2
- ADGRB3 | c.2414T>C p.I805T | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV65383243; called by muse, mutect2, varscan2
- ADGRV1 | c.7102A>G p.S2368G | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.374); catalogued as COSV67978684, COSV67997240; called by muse, mutect2, varscan2
- AFF3 | c.2215G>A p.E739K | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.575); catalogued as COSV100419764; called by muse, mutect2
- AKAP4 | c.872A>C p.E291A | Missense Mutation (SNP) | VAF 99/517 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.184); catalogued as COSV62073712; called by muse, mutect2, varscan2
- ANKZF1 | c.1205G>A p.G402D | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.71); catalogued as COSV99850805; called by muse, mutect2, varscan2
- ATF7 | c.325C>G p.L109V (on ENST00000548446 / NM_001366555.2; = p.L98V on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT tolerated (0.51); PolyPhen benign (0.146); catalogued as COSV60642229; called by muse, mutect2, varscan2
- ATG13 | c.872C>A p.A291D | Missense Mutation (SNP) | VAF 31/663 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); catalogued as COSV100365928; called by muse, mutect2
- BEX2 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.046); catalogued as COSV101012850; called by muse, mutect2
- BRINP1 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV56296019, COSV99776474; called by muse, mutect2
- BRWD3 | c.4499C>G p.S1500* | Nonsense Mutation (SNP) | VAF 13/66 reads (20%) | catalogued as COSV64744003; called by muse, mutect2
- CARS1 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 55/315 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53462036, COSV99543299; called by muse, mutect2, varscan2
- CCDC110 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.292); catalogued as rs767520981, COSV100294110; called by muse, mutect2, varscan2
- CCDC3 | c.584A>T p.E195V | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV66558513; called by muse, mutect2, varscan2
- CCL24 | c.5C>A p.A2E | Missense Mutation (SNP) | VAF 38/637 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.312); catalogued as COSV99768867; called by muse, mutect2
- CD276 | c.865G>T p.D289Y | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV100573413; called by mutect2, varscan2
- CDH1 | c.607G>A p.G203S | Missense Mutation (SNP) | VAF 40/554 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1215319435, COSV99932466; ClinVar: uncertain significance; called by muse, mutect2
- CDON | c.1965G>T p.M655I | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV54995202; called by muse, mutect2, varscan2
- CIB3 | c.516G>A p.M172I | Missense Mutation (SNP) | VAF 82/579 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.145); catalogued as COSV54165433; called by muse, mutect2, varscan2
- CLDN10 | c.185G>T p.R62L | Missense Mutation (SNP) | VAF 115/244 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as COSV65296459; called by muse, mutect2, varscan2
- COG8 | c.1171C>T p.Q391* | Nonsense Mutation (SNP) | VAF 17/62 reads (27%) | catalogued as COSV99650866; called by muse, mutect2, varscan2
- COL7A1 | c.8590C>T p.Q2864* | Nonsense Mutation (SNP) | VAF 15/137 reads (11%) | catalogued as COSV99866397; called by muse, mutect2
- COMTD1 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100041062; called by muse, varscan2
- COX15 | c.1195C>T p.L399F | Missense Mutation (SNP) | VAF 9/256 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as COSV99187438; called by muse, mutect2
- CPAMD8 | c.2083G>A p.D695N (on ENST00000651564; = p.D648N on NM_015692.5) | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.678); catalogued as rs1216563091, COSV52237404; called by muse, mutect2
- CYP2R1 | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 13/64 reads (20%) | catalogued as rs782803589, COSV58126681; called by muse, mutect2, varscan2
- DAW1 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 16/396 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as COSV100006408; called by muse, mutect2
- DHRS7 | c.936G>A p.M312I | Missense Mutation (SNP) | VAF 145/608 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV53665332; called by muse, mutect2, varscan2
- DIMT1 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.295); catalogued as COSV99551180; called by muse, varscan2
- DISP2 | c.1456G>A p.V486I | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.036); catalogued as rs758069989, COSV99140335; called by muse, varscan2
- DNAH3 | c.12067G>C p.E4023Q | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54503721, COSV54504721; called by muse, mutect2, varscan2
- DNAI1 | c.1580C>T p.S527F | Missense Mutation (SNP) | VAF 23/571 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV99647050; called by muse, mutect2
- DOCK2 | c.2561G>A p.R854Q | Missense Mutation (SNP) | VAF 91/191 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs752262388, COSV56942620, COSV56968077; called by muse, mutect2, varscan2
- DYSF | c.2570G>T p.W857L | Missense Mutation (SNP) | VAF 64/304 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50268706; called by muse, mutect2
- EFEMP2 | c.1044G>A p.M348I | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100337355; called by muse, mutect2, varscan2
- EIF3E | c.582G>C p.E194D | Missense Mutation (SNP) | VAF 70/373 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as rs1482317769, COSV55201495, COSV99622697; called by muse, mutect2, varscan2
- ELAPOR1 | c.2596G>A p.A866T | Missense Mutation (SNP) | VAF 14/247 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV100884464; called by muse, mutect2
- F13A1 | c.2179C>T p.Q727* | Nonsense Mutation (SNP) | VAF 36/1382 reads (3%) | catalogued as COSV99343660; called by muse, mutect2
- FAM171A1 | c.275A>C p.K92T | Missense Mutation (SNP) | VAF 17/428 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100968426; called by muse, mutect2
- FAM47B | c.1358C>G p.S453C | Missense Mutation (SNP) | VAF 74/320 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as COSV61452550; called by muse, mutect2, varscan2
- FAM71F1 | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100171099; called by muse, mutect2, varscan2
- FLT1 | c.3646G>T p.A1216S | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.012); catalogued as COSV99164917; called by muse, mutect2
- GLDC | c.1492G>C p.A498P | Missense Mutation (SNP) | VAF 233/564 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.584); catalogued as COSV58676581; called by muse, mutect2, varscan2
- GPS2 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.991); catalogued as rs774633910, COSV59747130; called by muse, mutect2, varscan2
- H2BC15 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV100357055; called by muse, mutect2, varscan2
- H2BC9 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.026); catalogued as rs370727098; called by muse, mutect2, varscan2
- HIVEP1 | c.6823G>A p.G2275R | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV101045535; called by muse, mutect2
- IFNA1 | c.442C>G p.R148G | Missense Mutation (SNP) | VAF 106/1082 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV52806429; called by muse, varscan2
- INTS6 | c.2236G>A p.E746K | Missense Mutation (SNP) | VAF 63/178 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as COSV100247199; called by muse, mutect2, varscan2
- JAK3 | c.3371C>T p.S1124L | Missense Mutation (SNP) | VAF 141/646 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV71685373; called by muse, varscan2
- JMJD4 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs1376599829, COSV100248376, COSV59919706; called by muse, mutect2, varscan2
- KANK1 | c.3138G>A p.M1046I | Missense Mutation (SNP) | VAF 80/2718 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV100620019; called by muse, mutect2
- KIAA1755 | c.2762G>T p.R921L | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs760553122, COSV99642458; called by muse, mutect2
- KLHL25 | c.1184dup p.H396Tfs*71 | Frame Shift Ins (INS) | VAF 5/37 reads (14%) | catalogued as rs778633792; called by mutect2, varscan2
- KLK3 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 121/588 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100386066; called by muse, mutect2, varscan2
- LPO | c.1196G>A p.R399K | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV51856830; called by muse, mutect2
- LRCH2 | c.2229A>T p.K743N | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57746175; called by muse, mutect2, varscan2
- LRRC37A3 | c.4814G>A p.C1605Y | Missense Mutation (SNP) | VAF 376/498 reads (76%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100141380; called by muse, mutect2, varscan2
- MANBA | c.2530G>T p.G844W (on ENST00000642252; = p.G798W on NM_005908.4) | Missense Mutation (SNP) | VAF 66/1176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99899037; called by muse, mutect2
- MAST2 | c.2189C>T p.P730L | Missense Mutation (SNP) | VAF 166/691 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs756675811, COSV63616167; called by muse, mutect2, varscan2
- MDN1 | c.15257C>T p.S5086F | Missense Mutation (SNP) | VAF 259/827 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101021664; called by muse, mutect2, varscan2
- METAP2 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV99704928; called by muse, varscan2
- MFHAS1 | c.2541G>T p.W847C | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99359815; called by muse, mutect2, varscan2
- MNDA | c.194T>G p.L65R | Missense Mutation (SNP) | VAF 89/323 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63739923, COSV63742122; called by muse, mutect2, varscan2
- MTG2 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762450102, COSV100895191; called by muse, mutect2, varscan2
- MTG2 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63693400; called by muse, mutect2, varscan2
- MYH1 | c.1157A>G p.K386R | Missense Mutation (SNP) | VAF 154/322 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV56843803; called by muse, varscan2
- MYH9 | c.2212C>T p.Q738* | Nonsense Mutation (SNP) | VAF 17/110 reads (15%) | catalogued as COSV53384315; called by muse, mutect2, varscan2
- N4BP3 | c.357G>T p.K119N | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99200777; called by muse, mutect2
- NBEA | c.3973C>T p.R1325W | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59760937; called by muse, mutect2, varscan2
- NECTIN3 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 16/436 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1317888347, COSV100162620; called by muse, mutect2
- NKRF | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 23/141 reads (16%) | catalogued as COSV100441828; called by muse, mutect2, varscan2
- NOP9 | c.1511G>A p.R504Q | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs139378596; called by muse, varscan2
- NUP210L | c.2212C>T p.H738Y | Missense Mutation (SNP) | VAF 17/330 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as rs866883415, COSV55157580; called by muse, mutect2
- NUP98 | c.4489A>G p.K1497E (on ENST00000359171 / NM_001365126.1; = p.K1480E on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 102/660 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100263164; called by muse, mutect2, varscan2
- OR10G7 | c.35T>A p.L12H | Missense Mutation (SNP) | VAF 57/206 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100390031, COSV57865637; called by muse, mutect2, varscan2
- OR5D14 | c.241C>A p.P81T | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59455310, COSV59455395; called by muse, varscan2
- OR8B8 | c.493G>C p.G165R | Missense Mutation (SNP) | VAF 426/854 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV60143737; called by muse, mutect2, varscan2
- PAF1 | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 25/844 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55395435; called by muse, mutect2
- PCDHAC1 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV99167918; called by muse, mutect2, varscan2
- PCDHB6 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 8/238 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.475); catalogued as COSV99170677; called by muse, mutect2
- PDE4A | c.2467G>A p.A823T (on ENST00000380702 / NM_001111307.2; = p.A584T on NM_006202.3) | Missense Mutation (SNP) | VAF 128/458 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.398); catalogued as COSV99534896; called by muse, varscan2
- PLCH1 | c.1012G>A p.E338K (on ENST00000340059 / NM_001130960.2; = p.E350K on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/205 reads (4%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.464); catalogued as COSV100397901; called by muse, mutect2
- PLEKHG2 | c.1495G>A p.G499R | Missense Mutation (SNP) | VAF 38/1448 reads (3%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52682211, COSV99218063; called by muse, mutect2
- PLEKHG6 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 178/298 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV99164786; called by muse, varscan2
- PRSS53 | c.1289C>T p.S430F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99762549; called by muse, mutect2, varscan2
- PTCH1 | c.1420G>A p.V474I | Missense Mutation (SNP) | VAF 133/321 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs766898310, COSV59463224, COSV59499687; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTCHD3 | c.22C>G p.P8A | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.003); catalogued as COSV101438949; called by muse, mutect2
- PTPN18 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs375251896; called by muse, mutect2, varscan2
- RAP1GAP2 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.973); catalogued as COSV99624035; called by muse, mutect2
- RGS7 | c.434T>A p.L145H | Missense Mutation (SNP) | VAF 184/545 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58531094; called by muse, mutect2, varscan2
- RIMS2 | c.2549A>C p.Y850S (on ENST00000666250 / NM_001348490.2; = p.Y658S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51653911; called by muse, mutect2, varscan2
- RNF19A | c.1939G>A p.G647S | Missense Mutation (SNP) | VAF 20/509 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV100347992; called by muse, mutect2
- RPS6KB1 | c.1510G>A p.G504R | Missense Mutation (SNP) | VAF 25/716 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.082); catalogued as COSV99847691; called by muse, mutect2
- RTKN | c.1117C>T p.Q373* (on ENST00000272430 / NM_001015055.2; = p.Q360* on NM_033046.2) | Nonsense Mutation (SNP) | VAF 110/1008 reads (11%) | catalogued as COSV99269844; called by muse, mutect2
- SALL3 | c.3760G>T p.G1254C | Missense Mutation (SNP) | VAF 51/64 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV73305765; called by muse, mutect2, varscan2
- SCAPER | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1216409563, COSV100239153; called by muse, mutect2
- SEMA4B | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.92); PolyPhen benign (0.06); catalogued as COSV100153371; called by muse, mutect2, varscan2
- SEMA6D | c.1605G>A p.W535* | Nonsense Mutation (SNP) | VAF 17/396 reads (4%) | catalogued as COSV100317388; called by muse, mutect2
- SGSM3 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.57); catalogued as rs780477111, COSV50651215; called by muse, mutect2, varscan2
- SH3GL1 | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 21/72 reads (29%) | catalogued as rs749316862, COSV53655937; called by muse, mutect2, varscan2
- SHOC1 | c.2148G>T p.K716N | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV59497698, COSV59500207; called by muse, mutect2, varscan2
- SHROOM2 | c.266C>G p.A89G | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101098945; called by muse, mutect2
- SIGLEC8 | c.734-1G>A p.X245_splice | Splice Site (SNP) | VAF 6/142 reads (4%) | catalogued as rs1282404549; called by muse, mutect2
- SLC4A10 | c.1711C>T p.P571S (on ENST00000446997 / NM_001354461.2; = p.P541S on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99765197; called by muse, mutect2
- SLC7A8 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 29/326 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1404757097, COSV100382367; called by muse, mutect2
- SOX15 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV100002170; called by muse, mutect2, varscan2
- TAC3 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 63/486 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as rs1383778839, COSV100269913; called by muse, varscan2
- TAF5 | c.1772C>G p.T591R | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV100428285; called by muse, mutect2
- TBX6 | c.539C>A p.A180D | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99661746; called by muse, mutect2
- TBXT | c.827G>A p.C276Y | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as COSV51616882; called by muse, mutect2, varscan2
- TCP11 | c.994G>T p.V332F (on ENST00000512012; = p.V270F on NM_018679.5) | Missense Mutation (SNP) | VAF 73/207 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.45); catalogued as rs765786893, COSV55131752, COSV55133326; called by muse, mutect2, varscan2
- TMOD1 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99404075; called by muse, mutect2, varscan2
- TNRC6A | c.1063G>A p.G355R | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs1440247251, COSV100170365; called by muse, mutect2
- TOGARAM1 | c.2975C>T p.S992L | Missense Mutation (SNP) | VAF 14/317 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.83); catalogued as COSV63892332; called by muse, mutect2
- TP73 | c.399G>T p.Q133H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60698538; called by muse, mutect2, varscan2
- TSPAN12 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 24/390 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as COSV99763307; called by muse, mutect2
- TTN | c.98806C>G p.Q32936E (on ENST00000591111; = p.Q25512E on NM_003319.4) | Missense Mutation (SNP) | VAF 132/604 reads (22%) | PolyPhen possibly damaging (0.717); catalogued as COSV59893179, COSV60293395; called by muse, mutect2, varscan2
- UBA2 | c.1246-1G>T p.X416_splice | Splice Site (SNP) | VAF 37/209 reads (18%) | catalogued as COSV55827325, COSV55829013; called by muse, mutect2, varscan2
- UBASH3A | c.1914C>G p.N638K | Missense Mutation (SNP) | VAF 104/615 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as COSV52310564; called by muse, mutect2, varscan2
- UGT1A7 | c.487C>T p.L163F | Missense Mutation (SNP) | VAF 32/648 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs529928629, COSV100693077; called by muse, mutect2
- URB2 | c.3529G>T p.A1177S | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV99271660; called by muse, mutect2
- VN1R4 | c.69C>G p.F23L | Missense Mutation (SNP) | VAF 65/183 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV60804643, COSV60805321; called by muse, varscan2
- VPS13C | c.3065C>G p.S1022C (on ENST00000644861 / NM_020821.3; = p.S979C on NM_017684.5) | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV99829473; called by muse, mutect2
- WDFY3 | c.7082C>T p.P2361L | Missense Mutation (SNP) | VAF 9/240 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as COSV55698103; called by muse, mutect2
- WDR6 | c.461G>A p.C154Y | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1186767522, COSV100556661; called by muse, varscan2
- ARHGAP45 | c.1426C>T p.Q476* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | called by muse, varscan2
- ARPP21 | c.1175G>A p.R392K | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- CRAT | c.1406_1441del p.R469_A481delinsP | In Frame Del (DEL) | VAF 46/522 reads (9%) | called by mutect2, pindel
- DCAF7 | c.52A>C p.T18P | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- FOXN4 | c.1387T>C p.S463P | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by mutect2, varscan2
- MRPL58 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 16/277 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2
- PCNT | c.943G>T p.E315* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | called by mutect2, varscan2
- PRPF8 | c.6286G>A p.D2096N | Missense Mutation (SNP) | VAF 78/320 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by mutect2, varscan2
- SHQ1 | c.1439T>C p.L480P | Missense Mutation (SNP) | VAF 83/307 reads (27%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by mutect2, varscan2
- SLC39A5 | c.1566_1567insGTGTTTGGGTGGGGG p.L522_M523insVFGWG | In Frame Ins (INS) | VAF 17/61 reads (28%) | called by mutect2, varscan2*
- WFDC8 | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 106/685 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF516 | c.1124G>A p.G375E | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.086); called by mutect2, varscan2
- ABCB6 | c.1746C>T p.P582= | Silent (SNP) | VAF 47/226 reads (21%) | called by muse, varscan2
- ADAM7 | c.1746G>A p.Q582= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as rs770997543, COSV99444671; called by muse, varscan2
- ALMS1 | c.2892C>T p.F964= | Silent (SNP) | VAF 39/606 reads (6%) | called by muse, mutect2
- ANKRD17 | c.7098C>T p.N2366= | Silent (SNP) | VAF 85/448 reads (19%) | catalogued as COSV58215547; called by muse, mutect2, varscan2
- ASH1L | c.4353C>T p.A1451= | Silent (SNP) | VAF 34/1266 reads (3%) | catalogued as COSV100853553; called by muse, mutect2
- ATP6V1H | c.390G>A p.L130= | Silent (SNP) | VAF 30/582 reads (5%) | catalogued as COSV100778762; called by muse, mutect2
- BTNL3 | c.639G>A p.Q213= | Silent (SNP) | VAF 9/174 reads (5%) | catalogued as COSV100732233; called by muse, mutect2
- CA14 | c.759G>A p.E253= | Silent (SNP) | VAF 72/802 reads (9%) | catalogued as rs149155658; called by muse, mutect2
- CALHM5 | c.267C>T p.P89= | Silent (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- CASP10 | c.73C>T p.L25= | Silent (SNP) | VAF 33/271 reads (12%) | called by mutect2, varscan2
- CEMIP2 | c.2844C>T p.S948= | Silent (SNP) | VAF 25/359 reads (7%) | catalogued as COSV100987145; called by muse, mutect2
- CES4A | c.106C>T p.L36= | Silent (SNP) | VAF 26/275 reads (9%) | called by muse, mutect2, varscan2
- COMTD1 | c.780C>T p.F260= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs940661307, COSV100041013, COSV100041061; called by muse, mutect2, varscan2
- DNAJC22 | c.15C>T p.L5= | Silent (SNP) | VAF 14/236 reads (6%) | catalogued as COSV101222591; called by muse, mutect2
- FAM117A | c.474G>A p.L158= | Silent (SNP) | VAF 18/410 reads (4%) | called by muse, mutect2
- FOXC2 | c.234C>T p.I78= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs1227098823, COSV100234140; called by mutect2, varscan2
- GSE1 | c.1377C>T p.P459= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99497050; called by muse, varscan2
- HPF1 | c.621C>T p.T207= | Silent (SNP) | VAF 34/150 reads (23%) | catalogued as COSV66421515, COSV66421589; called by muse, varscan2
- ID1 | c.27C>T p.A9= | Silent (SNP) | VAF 42/88 reads (48%) | catalogued as rs1215530011, COSV101076807; called by muse, mutect2, varscan2
- IGKV2D-29 | c.306G>C p.R102= | Silent (SNP) | VAF 58/313 reads (19%) | catalogued as COSV72391463; called by muse, mutect2, varscan2
- IGSF10 | c.7578C>T p.Y2526= | Silent (SNP) | VAF 12/339 reads (4%) | catalogued as rs1282512374, COSV99191769; called by muse, mutect2
- INTS6 | c.2235G>A p.L745= | Silent (SNP) | VAF 62/179 reads (35%) | catalogued as COSV100247201; called by muse, mutect2, varscan2
- KCNK16 | c.858C>G p.G286= | Silent (SNP) | VAF 75/211 reads (36%) | catalogued as COSV64677214; called by muse, mutect2, varscan2
- LILRB5 | c.1719C>T p.S573= (on ENST00000449561 / NM_001081442.3; = p.S572= on NM_006840.5) | Silent (SNP) | VAF 19/164 reads (12%) | catalogued as COSV100300678; called by muse, mutect2, varscan2
- LMX1A | c.145C>A p.R49= | Silent (SNP) | VAF 7/96 reads (7%) | catalogued as rs1359145261, COSV54217243, COSV99672897; called by muse, mutect2
- MAP3K11 | c.2292C>T p.I764= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV100442330; called by muse, mutect2, varscan2
- MAST2 | c.3534G>A p.L1178= | Silent (SNP) | VAF 85/506 reads (17%) | catalogued as COSV100788621; called by muse, mutect2, varscan2
- MBNL3 | c.807G>A p.K269= | Silent (SNP) | VAF 16/272 reads (6%) | catalogued as COSV100898509; called by muse, mutect2
- MCM3AP | c.2574G>A p.L858= | Silent (SNP) | VAF 6/144 reads (4%) | catalogued as COSV99387332; called by muse, mutect2
- NBEAL1 | c.4956C>T p.F1652= | Silent (SNP) | VAF 19/236 reads (8%) | catalogued as COSV71375432; called by muse, mutect2
- NCOA6 | c.1815C>T p.N605= | Silent (SNP) | VAF 27/168 reads (16%) | catalogued as COSV100750250; called by muse, varscan2
- NLRC4 | c.2038C>T p.L680= | Silent (SNP) | VAF 11/226 reads (5%) | catalogued as COSV100707478; called by muse, mutect2
- OR2AG1 | c.855G>A p.L285= | Silent (SNP) | VAF 30/336 reads (9%) | catalogued as COSV100264930, COSV100264937; called by muse, mutect2
- OR2AT4 | c.357C>T p.I119= | Silent (SNP) | VAF 8/194 reads (4%) | catalogued as COSV59407680; called by muse, mutect2
- OR6V1 | c.228G>A p.V76= | Silent (SNP) | VAF 58/1091 reads (5%) | catalogued as COSV69237369; called by muse, mutect2
- PCDHAC1 | c.282C>T p.V94= | Silent (SNP) | VAF 31/119 reads (26%) | catalogued as COSV99167917; called by muse, mutect2, varscan2
- PDE12 | c.570C>T p.P190= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as COSV100239932; called by muse, mutect2, varscan2
- PLCG1 | c.3780C>T p.F1260= (on ENST00000373271 / NM_182811.2; = p.F1261= on NM_002660.3) | Silent (SNP) | VAF 30/432 reads (7%) | catalogued as rs200825598, COSV99719136; called by muse, mutect2
- PNMA8A | c.1068G>A p.K356= | Silent (SNP) | VAF 364/873 reads (42%) | catalogued as COSV58135652, COSV58138257; called by muse, mutect2, varscan2
- PRAMEF1 | c.396G>A p.R132= | Silent (SNP) | VAF 62/1206 reads (5%) | catalogued as rs753961214; called by muse, mutect2
- PROM2 | c.162T>G p.V54= | Silent (SNP) | VAF 29/124 reads (23%) | catalogued as COSV58296691; called by muse, mutect2, varscan2
- RBM12B | c.2283G>A p.E761= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV101234549; called by mutect2, varscan2
- RRP1 | c.528G>A p.E176= | Silent (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- SLC4A11 | c.726G>A p.E242= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV101196105; called by mutect2, varscan2
- SPAG9 | c.3795C>T p.P1265= (on ENST00000262013 / NM_001130528.3; = p.P1251= on NM_003971.6) | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as COSV100005710, COSV100005963; called by muse, mutect2, varscan2
- SYNE1 | c.15729G>A p.S5243= (on ENST00000367255 / NM_182961.4; = p.S5172= on NM_033071.3) | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as rs1417590001, COSV54930824; called by muse, varscan2
- TAS2R41 | c.168C>T p.F56= | Silent (SNP) | VAF 55/483 reads (11%) | catalogued as COSV101281510; called by muse, mutect2, varscan2
- TULP2 | c.1347C>T p.T449= | Silent (SNP) | VAF 55/420 reads (13%) | catalogued as COSV99668023; called by muse, mutect2, varscan2
- UBXN10 | c.39G>A p.E13= | Silent (SNP) | VAF 45/215 reads (21%) | catalogued as rs534420264, COSV66771833; called by muse, mutect2, varscan2
- VCAN | c.435G>A p.L145= | Silent (SNP) | VAF 32/230 reads (14%) | catalogued as COSV99426828; called by muse, varscan2
- VDAC1 | c.252G>A p.E84= | Silent (SNP) | VAF 250/1636 reads (15%) | catalogued as COSV99527300; called by muse, mutect2, varscan2
- VN1R4 | c.321C>A p.I107= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as COSV60804638, COSV60804854; called by muse, mutect2, varscan2
- ZFP36 | c.120C>T p.S40= (on ENST00000594442; = p.S34= on NM_003407.5) | Silent (SNP) | VAF 20/500 reads (4%) | catalogued as COSV50528592; called by muse, mutect2
- ZNF774 | c.369C>A p.T123= | Silent (SNP) | VAF 8/131 reads (6%) | catalogued as COSV100586437; called by muse, mutect2
- AL353804.7 | chrX:73845935 ins A | 5'Flank (INS) | VAF 24/265 reads (9%) | called by pindel, varscan2
- FOLH1B | n.1268G>A | RNA (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
- RBM44 | c.-98-2597G>A | Intron (SNP) | VAF 8/62 reads (13%) | catalogued as COSV57627259; called by muse, mutect2
- RORA | c.197-25058G>A | Intron (SNP) | VAF 18/586 reads (3%) | catalogued as COSV99832899; called by muse, mutect2
- STMP1 | chr7:135660261 A>G | 5'Flank (SNP) | VAF 205/464 reads (44%) | catalogued as rs776334105; called by muse, mutect2, varscan2
